Somatic mutation profile of tumor specimen TCGA-22-5491-01A (aliquot TCGA-22-5491-01A-01D-1632-08) from TCGA case TCGA-22-5491, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.3 years (27,145 days).
Specimen TCGA-22-5491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba6d4cd3-d079-4a03-9aa9-493e2690fff5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5491-11A (Solid Tissue Normal), aliquot TCGA-22-5491-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d427a6b4-e29d-42cf-8e95-de93b5000c4f

The open-access MAF lists 350 somatic variants for this specimen: 270 protein-altering or splice-affecting, 68 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 231, Silent 68, Nonsense Mutation 23, Frame Shift Del 7, Intron 5, Splice Site 5, RNA 3, 3'UTR 2, Splice Region 2, Frame Shift Ins 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 33/50 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.1329G>T p.M443I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV53974689; called by muse, mutect2, varscan2
- ABTB2 | c.2687A>G p.H896R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV54389838; called by muse, mutect2, varscan2
- ABTB2 | c.954T>G p.D318E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV54389851; called by muse, mutect2, varscan2
- ACKR1 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV63673160, COSV63673176; called by muse, mutect2, varscan2
- ADAM29 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV63664471; called by muse, mutect2, varscan2
- ADAMTS2 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 110/158 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51082508; called by muse, mutect2, varscan2
- ADCY8 | c.3230T>C p.I1077T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53911493; called by muse, mutect2, varscan2
- ADGRE1 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51676681; called by muse, mutect2, varscan2
- ADRA2C | c.546C>G p.I182M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57467408; called by muse, mutect2
- AGMO | c.1330T>A p.W444R | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.07); catalogued as COSV61114550; called by muse, mutect2, varscan2
- AHNAK2 | c.16442G>A p.S5481N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.534); catalogued as COSV60917920; called by muse, mutect2
- ANKFN1 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59449560; called by muse, mutect2, varscan2
- ANKFY1 | c.2237G>T p.R746L (on ENST00000341657 / NM_001330063.2; = p.R747L on NM_016376.5) | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58918602, COSV58920120; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4753G>T p.G1585C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51848917; called by muse, mutect2, varscan2
- ARHGAP32 | c.4714G>A p.E1572K (on ENST00000310343 / NM_001378025.1; = p.E1223K on NM_014715.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs200206728, COSV59843905; called by muse, mutect2, varscan2
- ARHGAP36 | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 71/87 reads (82%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.069); catalogued as COSV52267824; called by muse, mutect2, varscan2
- ATP13A5 | c.2476A>G p.M826V | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV60870403; called by muse, mutect2, varscan2
- ATP1A2 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV63401929; called by muse, mutect2, varscan2
- ATP2A2 | c.2774C>G p.P925R | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57875568; called by muse, mutect2, varscan2
- ATRAID | c.661C>T p.P221S (on ENST00000611786; = p.P108S on NM_016085.5) | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53027798; called by muse, mutect2, varscan2
- BAZ2B | c.2429G>C p.R810T | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as COSV58602678; called by muse, mutect2, varscan2
- BHMT | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57154611; called by muse, mutect2
- BICD2 | c.272A>T p.K91M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63549324; called by muse, mutect2, varscan2
- BMX | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV59591750; called by muse, mutect2, varscan2
- BTN2A2 | c.1552G>T p.G518W | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV61857700; called by muse, mutect2, varscan2
- C1QL1 | c.323C>A p.P108Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV53647351; called by muse, mutect2
- C1QTNF6 | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV55396559; called by muse, mutect2, varscan2
- CALCRL | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as rs769875438, COSV66475390; called by muse, mutect2, varscan2
- CAMK4 | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV56673041; called by muse, mutect2, varscan2
- CAMLG | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51804855; called by muse, mutect2, varscan2
- CARD11 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV62754649; called by muse, mutect2, varscan2
- CASD1 | c.1501G>T p.V501L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51973079; called by muse, mutect2, varscan2
- CASP8AP2 | c.5854G>C p.A1952P | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV52747738; called by muse, mutect2, varscan2
- CATSPER2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 70/387 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58661032; called by muse, mutect2, varscan2
- CCDC110 | c.1284T>G p.I428M | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56871800; called by muse, mutect2, varscan2
- CCDC146 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV53549711; called by muse, mutect2, varscan2
- CCDC173 | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV69573181; called by muse, mutect2, varscan2
- CCDC66 | c.718G>C p.E240Q (on ENST00000394672 / NM_001353147.1; = p.E206Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.133); catalogued as COSV58304964; called by muse, mutect2, varscan2
- CCDC8 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 52/140 reads (37%) | catalogued as rs1286533212, COSV56773727; called by muse, mutect2, varscan2
- CD6 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV57839442; called by muse, mutect2, varscan2
- CGRRF1 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 43/150 reads (29%) | catalogued as COSV53596990; called by muse, mutect2, varscan2
- CHRNG | c.867C>A p.F289L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV67315648; called by muse, mutect2, varscan2
- CIITA | c.2831C>G p.S944W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV60858342; called by muse, mutect2, varscan2
- CLDN12 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV55307109; called by muse, mutect2
- COL11A1 | c.4027C>A p.Q1343K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.9); catalogued as COSV62185807; called by muse, mutect2, varscan2
- COL1A1 | c.3002G>A p.G1001D | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56806036; called by muse, mutect2, varscan2
- COL6A6 | c.4602C>A p.G1534= | Splice Region (SNP) | VAF 15/117 reads (13%) | catalogued as COSV62027492, COSV62035808; called by muse, mutect2, varscan2
- CPZ | c.343C>T p.R115C (on ENST00000360986 / NM_001014447.3; = p.R104C on NM_003652.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as rs751661493, COSV59921712; called by muse, mutect2, varscan2
- CRLF3 | c.957C>G p.F319L | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60836081, COSV60836913; called by muse, mutect2, varscan2
- CSMD3 | c.2625T>A p.C875* (on ENST00000297405 / NM_001363185.1; = p.C771* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 59/163 reads (36%) | catalogued as COSV52204716; called by muse, mutect2, varscan2
- CT47A6 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV70031687; called by muse, varscan2
- CTIF | c.671A>G p.Q224R | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.138); catalogued as COSV56485394; called by muse, mutect2, varscan2
- CUX1 | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV52902524; called by muse, mutect2, varscan2
- CYP11B1 | c.1403T>A p.L468Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52827902; called by muse, mutect2, varscan2
- DCAF17 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV59830456; called by muse, mutect2, varscan2
- DCAF7 | c.687G>C p.W229C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV60407770; called by muse, mutect2, varscan2
- DDI1 | c.845T>G p.V282G | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56380858; called by muse, mutect2, varscan2
- DDX60L | c.1239T>G p.F413L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV52714949; called by muse, mutect2
- DGAT1 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60048368; called by muse, mutect2, varscan2
- DHX36 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 143/224 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs755829356, COSV57672502; called by muse, mutect2, varscan2
- DNAH5 | c.12125G>C p.R4042P | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV54231173, COSV54250830; called by muse, mutect2, varscan2
- DNAH5 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.076); catalogued as COSV54231183, COSV54237929; called by muse, mutect2, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, mutect2, varscan2
- DOK5 | c.323A>C p.Q108P | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as COSV52821386; called by muse, mutect2, varscan2
- DST | c.12494G>A p.G4165D (on ENST00000361203 / NM_001374722.1; = p.G1753D on NM_015548.5) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55019593; called by muse, mutect2, varscan2
- DYNC1H1 | c.7928G>T p.R2643L | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100794663, COSV64137932; called by muse, varscan2
- DYSF | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV50448634, COSV50474723; called by muse, mutect2, varscan2
- EFCAB13 | c.1930C>A p.L644I | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV58949361; called by muse, mutect2, varscan2
- EGFLAM | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV59305170; called by muse, mutect2, varscan2
- EPB41L1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.587); catalogued as COSV52438936; called by muse, mutect2, varscan2
- EPG5 | c.5971G>T p.E1991* | Nonsense Mutation (SNP) | VAF 57/125 reads (46%) | catalogued as COSV56351016; called by muse, mutect2, varscan2
- EPHA3 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV60694261; called by muse, mutect2, varscan2
- ESR2 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV50832766, COSV99962948; called by muse, mutect2, varscan2
- FAM126B | c.911A>C p.E304A | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV53773073; called by muse, mutect2, varscan2
- FAM172A | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV67938519; called by muse, mutect2, varscan2
- FAM172A | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV67938523; called by muse, mutect2, varscan2
- FBXW10 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV57318365; called by muse, mutect2, varscan2
- FERMT3 | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV54180638; called by muse, mutect2, varscan2
- FLG | c.2306G>A p.G769D | Missense Mutation (SNP) | VAF 222/533 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV64242911, COSV64251652; called by muse, mutect2, varscan2
- FLG2 | c.6490C>G p.Q2164E | Missense Mutation (SNP) | VAF 184/452 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV66169335; called by muse, mutect2, varscan2
- GABRA5 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59477765; called by muse, mutect2, varscan2
- GABRB3 | c.1061C>G p.S354* | Nonsense Mutation (SNP) | VAF 18/325 reads (6%) | catalogued as COSV54652613, COSV54668324; called by muse, mutect2
- GAD2 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV52159596; called by muse, mutect2, varscan2
- GAP43 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV59344860; called by muse, mutect2
- GCC2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV59177036; called by muse, mutect2
- GNB2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV51942901; called by muse, mutect2, varscan2
- GNG12 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV63972819; called by muse, mutect2, varscan2
- GNPDA2 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV54947020; called by muse, mutect2, varscan2
- GON4L | c.5050C>T p.Q1684* | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | catalogued as COSV55195402; called by muse, mutect2, varscan2
- GPR148 | c.1013G>T p.R338M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV59308525; called by muse, mutect2, varscan2
- GPRIN2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs782785817, COSV65401239, COSV65402259; called by muse, mutect2
- GRM1 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV51167062; called by muse, mutect2, varscan2
- GRM1 | c.2092C>A p.P698T | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51167368; called by muse, mutect2, varscan2
- H1-7 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771230698, COSV58602266; called by muse, mutect2, varscan2
- H2AZ1 | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56454740, COSV56455380; called by muse, mutect2, varscan2
- HAS1 | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55787952; called by muse, mutect2, varscan2
- HMGCS2 | c.1188C>A p.H396Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV65568142; called by muse, mutect2, varscan2
- HOMEZ | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV62537253; called by muse, mutect2
- HOXA7 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV54217981; called by muse, mutect2, varscan2
- IFNA8 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV66504656; called by muse, mutect2, varscan2
- IQCG | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 841/1136 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV54562810; called by muse, mutect2, varscan2
- JAK1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV61092347; called by muse, mutect2, varscan2
- JARID2 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59190823; called by muse, mutect2, varscan2
- JMJD1C | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.584); catalogued as rs1470580755, COSV59515896; called by muse, mutect2, varscan2
- KCNA6 | c.1006A>C p.M336L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV54975759; called by muse, mutect2, varscan2
- KCND2 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58583790, COSV58601749; called by muse, mutect2, varscan2
- KCND3 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV56182312; called by muse, mutect2, varscan2
- KCNK13 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV56413772; called by muse, mutect2, varscan2
- KCNMA1 | c.1518C>G p.I506M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54254412; called by muse, mutect2, varscan2
- KLB | c.2729A>T p.Y910F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763639126, COSV57302282; called by muse, mutect2, varscan2
- KMT2A | c.4006G>T p.E1336* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV63286823, COSV63292830; called by muse, mutect2, varscan2
- KPNA2 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 69/319 reads (22%) | catalogued as COSV57857971; called by muse, mutect2, varscan2
- KREMEN1 | c.238G>A p.E80K (on ENST00000407188; = p.E82K on NM_032045.5) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as COSV59912496, COSV59913255; called by muse, mutect2, varscan2
- LAS1L | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56707691; called by muse, mutect2, varscan2
- LPIN1 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV56766473; called by muse, mutect2, varscan2
- LRAT | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV60477293; called by muse, mutect2, varscan2
- LRP1B | c.9625G>T p.V3209F | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs77794732, COSV67231336, COSV67250866, COSV67284629; called by muse, mutect2, varscan2
- LRP2 | c.9178G>A p.G3060R | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as rs773430993, COSV55557332, COSV99786890; called by muse, mutect2, varscan2
- LRP2 | c.4922T>C p.I1641T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs1035756737, COSV55557341; called by muse, mutect2, varscan2
- LRRC4C | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs772469219, COSV53428015; called by muse, mutect2, varscan2
- LRRK2 | c.1646C>A p.A549D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs1305033151, COSV54156066; called by muse, mutect2, varscan2
- MAP10 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV69363865; called by muse, mutect2
- MAP1A | c.8272A>T p.T2758S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55809673; called by muse, mutect2, varscan2
- MAS1 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as COSV53121367; called by muse, mutect2, varscan2
- MICALL1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53241154; called by muse, mutect2, varscan2
- MORC2 | c.247C>T p.Q83* (on ENST00000397641 / NM_001303256.3; = p.Q21* on NM_014941.3) | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | catalogued as COSV53199468; called by muse, mutect2, varscan2
- MROH2B | c.3961C>A p.Q1321K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.552); catalogued as COSV68185198, COSV68185945; called by muse, mutect2, varscan2
- MTMR11 | c.1016C>T p.S339L (on ENST00000439741 / NM_001145862.2; = p.S267L on NM_181873.3) | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54965741; called by muse, mutect2, varscan2
- MUC4 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1297324252, COSV62155762; called by muse, mutect2
- MUC4 | c.2492C>T p.S831L | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV62155771; called by muse, mutect2, varscan2
- MUC4 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 60/608 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV62155774; called by muse, mutect2, varscan2
- MYB | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV100214935, COSV57198781; called by muse, mutect2, varscan2
- MYH2 | c.3397del p.A1133Pfs*37 | Frame Shift Del (DEL) | VAF 37/78 reads (47%) | catalogued as COSV55442232; called by mutect2, pindel, varscan2
- MYO16 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs201258873; called by muse, mutect2, varscan2
- MYO1E | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV55688943; called by muse, mutect2, varscan2
- MYO6 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as CM1310471, COSV64119436; called by muse, mutect2, varscan2
- NAP1L2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as rs1468267679, COSV65172142; called by muse, mutect2
- NGEF | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV50926732; called by muse, mutect2, varscan2
- NLRP12 | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1170715499, COSV60748979; called by muse, mutect2, varscan2
- NOLC1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV64180595; called by muse, mutect2, varscan2
- NOX3 | c.1565C>A p.A522D | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50153928; called by muse, mutect2, varscan2
- NPAP1 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV61507843; called by muse, varscan2
- NRARP | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV63082880; called by muse, mutect2, varscan2
- NRARP | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV63082886, COSV63083075; called by muse, mutect2, varscan2
- NRCAM | c.2698G>A p.E900K (on ENST00000379028 / NM_001371124.1; = p.E884K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.19); catalogued as COSV100694333, COSV61039030; called by muse, mutect2, varscan2
- NRDC | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as COSV61405073; called by muse, mutect2, varscan2
- NUP107 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57495311; called by muse, mutect2, varscan2
- NUP155 | c.3019G>A p.D1007N (on ENST00000231498 / NM_153485.3; = p.D948N on NM_004298.4) | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV51530806; called by muse, mutect2, varscan2
- NUP42 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.938); catalogued as COSV51729937; called by muse, mutect2, varscan2
- NYNRIN | c.4067C>A p.A1356E | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV66843043; called by muse, mutect2
- OBSCN | c.21004C>T p.Q7002* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs759639010, COSV62529569; called by muse, mutect2, varscan2
- OFD1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 153/170 reads (90%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as rs373202088, COSV60796395; called by muse, mutect2, varscan2
- OR2G2 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60740804, COSV60740826; called by muse, mutect2, varscan2
- OR3A3 | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99351346; called by muse, mutect2, varscan2
- OR52E2 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58612791; called by muse, mutect2, varscan2
- OR5J2 | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV56621842, COSV56621992, COSV56622459; called by muse, mutect2, varscan2
- PAPOLB | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs1235765326, COSV68201525; called by muse, mutect2
- PCDH18 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61269199; called by mutect2, varscan2
- PCDHGA2 | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.021); catalogued as COSV53964376; called by muse, mutect2
- PDE8A | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV59637637; called by muse, mutect2, varscan2
- PGRMC1 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.669); catalogued as rs760260698, COSV54292928; called by muse, mutect2, varscan2
- PI16 | c.510C>A p.N170K | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV65447992, COSV65448276; called by muse, mutect2, varscan2
- PKHD1L1 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as rs752378228, COSV65739508; called by muse, mutect2
- PLCH1 | c.1549G>T p.A517S (on ENST00000340059 / NM_001130960.2; = p.A529S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV58200325; called by muse, mutect2, varscan2
- PLPPR2 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as COSV52260483; called by muse, mutect2, varscan2
- PNPLA6 | c.3001G>C p.E1001Q (on ENST00000414982 / NM_001166111.2; = p.E953Q on NM_006702.5) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.359); catalogued as COSV55379539; called by muse, varscan2
- POLE | c.286-2A>T p.X96_splice | Splice Site (SNP) | VAF 48/120 reads (40%) | catalogued as COSV57674789; called by muse, mutect2, varscan2
- POLL | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs1489594256, COSV54575865; called by muse, mutect2
- PPFIA4 | c.2269A>G p.I757V (on ENST00000447715; = p.I758V on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV55316347; called by muse, mutect2, varscan2
- PPP1R15B | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65815896; called by muse, mutect2, varscan2
- PREX2 | c.2806A>G p.T936A | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV55776369; called by muse, mutect2, varscan2
- PRKCI | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV55519635; called by muse, mutect2
- PTPN14 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); catalogued as COSV65284827; called by muse, varscan2
- PTPRF | c.3103C>G p.P1035A | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63445831; called by muse, mutect2, varscan2
- PTPRK | c.1163-1G>A p.X388_splice | Splice Site (SNP) | VAF 14/85 reads (16%) | catalogued as COSV63899780; called by muse, mutect2, varscan2
- PTPRN | c.2729+2T>A p.X910_splice | Splice Site (SNP) | VAF 19/46 reads (41%) | catalogued as COSV55348942; called by muse, mutect2, varscan2
- PTTG1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 128/195 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs376226386; called by muse, mutect2, varscan2
- RAB21 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54228981; called by muse, mutect2, varscan2
- RAB34 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV56387067; called by muse, mutect2, varscan2
- RELCH | c.1600G>C p.V534L | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV56886619; called by muse, mutect2, varscan2
- RESF1 | c.2003G>T p.C668F | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV57022877; called by muse, mutect2, varscan2
- RIC1 | c.3011C>G p.S1004* | Nonsense Mutation (SNP) | VAF 179/272 reads (66%) | catalogued as COSV52610532; called by muse, mutect2, varscan2
- RSAD2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs568401913, COSV65908422; called by muse, mutect2, varscan2
- RSPO2 | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.21); catalogued as COSV52646290; called by muse, mutect2, varscan2
- RTL9 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV71825705; called by muse, mutect2, varscan2
- RYR1 | c.3043C>A p.R1015S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV62099806; called by muse, mutect2, varscan2
- RYR2 | c.3535G>T p.G1179C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63690180; called by muse, mutect2, varscan2
- RYR2 | c.3536G>T p.G1179V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63690185; called by muse, mutect2, varscan2
- RYR2 | c.11591A>G p.N3864S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs794728776, COSV63690188; ClinVar: uncertain significance; called by muse, mutect2
- RYR3 | c.2745G>C p.E915D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV66793831, COSV66797875; called by muse, mutect2
- SAP30BP | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53128392; called by muse, mutect2, varscan2
- SATB1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.123); catalogued as COSV58667948, COSV58670095; called by muse, mutect2, varscan2
- SCARF1 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV53959156; called by muse, mutect2, varscan2
- SCN4A | c.4645G>A p.G1549R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.787); catalogued as rs748122664, COSV71127252; called by mutect2, varscan2
- SERPINI1 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55511488; called by muse, mutect2
- SIPA1L3 | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV55916321; called by muse, mutect2, varscan2
- SKP1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV60435859; called by muse, mutect2, varscan2
- SLC15A2 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV55198342; called by muse, mutect2
- SLC17A8 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.045); catalogued as COSV60123113, COSV60124368; called by muse, mutect2, varscan2
- SLC26A5 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59702563; called by muse, mutect2, varscan2
- SLC39A1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV57843403; called by muse, mutect2, varscan2
- SLC44A1 | c.1642G>T p.V548F | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58264896; called by muse, mutect2, varscan2
- SLC6A19 | c.1380C>T p.G460= | Splice Region (SNP) | VAF 9/54 reads (17%) | catalogued as rs774369073, COSV58671895; called by muse, mutect2, varscan2
- SLITRK2 | c.2482T>A p.S828T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59426044; called by muse, mutect2, varscan2
- SLITRK2 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV59426050; called by muse, mutect2, varscan2
- SMOX | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV53865655; called by muse, mutect2, varscan2
- SNAP91 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52124321; called by muse, mutect2, varscan2
- SORCS3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV63803612; called by muse, mutect2, varscan2
- SOX5 | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 90/217 reads (41%) | catalogued as COSV58633088; called by muse, mutect2, varscan2
- SPEG | c.9617G>A p.R3206Q | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1411781409, COSV56670986, COSV56673248; called by muse, mutect2
- SSH2 | c.1640A>G p.N547S | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52173778; called by muse, mutect2, varscan2
- STXBP5 | c.2342C>T p.S781L (on ENST00000321680 / NM_001127715.2; = p.S745L on NM_139244.4) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51653440; called by muse, mutect2, varscan2
- SUGP2 | c.2051G>C p.R684P | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as COSV100431427, COSV58260177, COSV58264968; called by muse, mutect2, varscan2
- SYNE1 | c.3911G>A p.G1304E (on ENST00000367255 / NM_182961.4; = p.G1311E on NM_033071.3) | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs141164314, COSV55005170; called by muse, mutect2, varscan2
- SYT1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV54034598, COSV54052131; called by muse, mutect2, varscan2
- TBCD | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV62799292, COSV62802310; called by muse, mutect2, varscan2
- TERT | c.2794G>A p.G932S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761308654, COSV57206374; called by muse, mutect2
- TET1 | c.4462-2A>C p.X1488_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV65385534; called by muse, mutect2, varscan2
- THSD7A | c.4199A>G p.N1400S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV69855820; called by muse, mutect2, varscan2
- THSD7A | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs746269442, COSV70266175; called by muse, mutect2, varscan2
- TKTL2 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54917910, COSV54919438; called by muse, mutect2, varscan2
- TMTC3 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.061); catalogued as COSV57124339; called by muse, mutect2, varscan2
- TNN | c.3150C>A p.S1050R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757566890, COSV53428077; called by muse, mutect2, varscan2
- TOX4 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.116); catalogued as rs1450842056, COSV52969378; called by muse, mutect2, varscan2
- TPD52 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV66950684; called by muse, mutect2, varscan2
- TPH2 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV61592433; called by muse, mutect2, varscan2
- TRIP4 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV56031302; called by muse, mutect2, varscan2
- UBN1 | c.2371C>T p.H791Y | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as rs1485515104, COSV52166435; called by muse, mutect2, varscan2
- VEGFC | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV54599424; called by muse, mutect2, varscan2
- YWHAQ | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); catalogued as COSV53003579; called by muse, mutect2, varscan2
- ZBTB12 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.031); catalogued as COSV64993933; called by muse, mutect2, varscan2
- ZBTB12 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); catalogued as COSV64993937; called by muse, mutect2, varscan2
- ZFC3H1 | c.1607A>T p.D536V | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV66433390; called by muse, mutect2, varscan2
- ZFC3H1 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV66433395; called by muse, mutect2, varscan2
- ZFHX3 | c.10802C>G p.S3601W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV51721517, COSV51736031; called by muse, mutect2, varscan2
- ZFR2 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV53597085, COSV53599582; called by muse, mutect2, varscan2
- ZKSCAN3 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV52852812; called by muse, mutect2, varscan2
- ZMPSTE24 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs373684692, COSV65639406, COSV65640266; called by muse, mutect2, varscan2
- ZNF100 | c.566T>A p.F189Y | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV59748171; called by muse, mutect2, varscan2
- ZNF174 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51903009; called by muse, mutect2, varscan2
- ZNF208 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as COSV68101588, COSV68107479; called by muse, mutect2, varscan2
- ZNF232 | c.1052G>C p.R351T | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100005748, COSV51503755; called by muse, mutect2, varscan2
- ZNF385A | c.316G>C p.E106Q (on ENST00000338010 / NM_001130967.3; = p.E86Q on NM_015481.3) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61493573; called by muse, mutect2, varscan2
- ZNF418 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs746047456, COSV68675966; called by muse, mutect2, varscan2
- ZNF544 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | catalogued as COSV54136270; called by muse, mutect2, varscan2
- ZNF560 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 114/340 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV100038929, COSV56868544; called by muse, mutect2, varscan2
- ZNF571 | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1174545264, COSV60733168; called by muse, mutect2, varscan2
- ZNF571 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | catalogued as rs1284959181, COSV60733472; called by muse, mutect2, varscan2
- ZNF585B | c.448A>C p.K150Q | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as COSV57215918; called by muse, mutect2, varscan2
- ZNF600 | c.417T>A p.Y139* | Nonsense Mutation (SNP) | VAF 84/224 reads (38%) | catalogued as COSV57741740, COSV57743056; called by muse, mutect2, varscan2
- ZNF606 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV62046921; called by muse, mutect2, varscan2
- ZNF676 | c.154C>A p.L52M (on ENST00000650058; = p.L20M on NM_001001411.3) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV68092257, COSV68093380; called by muse, mutect2
- ZNF776 | c.1433A>C p.H478P | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57815469; called by muse, mutect2, varscan2
- ZNRF3 | c.2048C>T p.S683L (on ENST00000544604 / NM_001206998.2; = p.S583L on NM_032173.3) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as COSV60431333; called by muse, mutect2, varscan2
- CYP2A7 | c.181-1G>C p.X61_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- ELL3 | c.991_995del p.L331Sfs*4 | Frame Shift Del (DEL) | VAF 39/107 reads (36%) | called by mutect2, pindel, varscan2
- FCGBP | c.6460G>A p.D2154N | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.157); called by muse, mutect2
- FCGBP | c.5278C>A p.L1760I | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- IGHV7-81 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- LNPK | c.1198del p.A400Pfs*3 | Frame Shift Del (DEL) | VAF 56/178 reads (31%) | called by mutect2, pindel, varscan2
- NPAT | c.1987del p.S663Hfs*4 | Frame Shift Del (DEL) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- OS9 | c.524_525del p.Y175Wfs*9 | Frame Shift Del (DEL) | VAF 41/133 reads (31%) | called by mutect2, pindel, varscan2
- PDCL2 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.517); called by muse, varscan2
- PIP4K2B | c.350A>T p.Y117F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TEX15 | c.6319del p.E2107Kfs*21 (on ENST00000256246; = p.E2490Kfs*21 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 32/56 reads (57%) | called by mutect2, pindel, varscan2
- TRBV3-1 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TTK | c.1200dup p.A401Cfs*17 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- TTK | c.1201delinsTT p.A401Ffs*17 | Frame Shift Ins (INS) | VAF 9/79 reads (11%) | called by mutect2*, pindel, varscan2*
- WDR76 | c.1129_1130del p.L377Vfs*5 | Frame Shift Del (DEL) | VAF 26/239 reads (11%) | called by mutect2, pindel, varscan2
- ABCB4 | c.2331G>A p.G777= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as COSV55936409; called by muse, mutect2, varscan2
- ADAM23 | c.2337C>A p.P779= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs571615571, COSV52217714; called by muse, mutect2, varscan2
- ADAMTS19 | c.1665C>T p.V555= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV50754859; called by muse, mutect2, varscan2
- ADAMTS2 | c.816G>T p.L272= | Silent (SNP) | VAF 111/158 reads (70%) | catalogued as COSV51082593; called by muse, mutect2, varscan2
- ADAMTS9 | c.5268G>A p.L1756= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV55783023; called by muse, mutect2, varscan2
- BBS9 | c.2397G>A p.L799= (on ENST00000242067 / NM_001348036.1; = p.L759= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as rs762435424, COSV54171736; called by muse, mutect2, varscan2
- BRD1 | c.2610G>T p.A870= (on ENST00000216267 / NM_001349940.1; = p.A1001= on NM_001304808.3) | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as rs376099852, COSV53458181; called by muse, mutect2, varscan2
- CDH12 | c.2148C>T p.F716= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV66412000; called by muse, mutect2, varscan2
- CHRNG | c.1173C>G p.L391= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV67315311; called by muse, mutect2, varscan2
- CLTRN | c.668G>A p.*223= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV66712055; called by muse, mutect2, varscan2
- CLVS2 | c.276C>A p.T92= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as COSV51564011; called by muse, mutect2, varscan2
- CNGA4 | c.1626C>T p.P542= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs560979109, COSV66005473; called by muse, mutect2, varscan2
- CNOT6 | c.1515C>A p.I505= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV56161941; called by muse, mutect2, varscan2
- COL11A1 | c.4200T>G p.P1400= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV62185799; called by muse, mutect2, varscan2
- COL11A2 | c.4911C>T p.L1637= (on ENST00000341947 / NM_080680.3; = p.L1530= on NM_080679.2) | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs775496793, COSV59497946; called by muse, mutect2
- CRLF2 | c.321C>T p.F107= | Silent (SNP) | VAF 21/244 reads (9%) | catalogued as COSV67493838; called by muse, mutect2
- CUL9 | c.2568G>A p.L856= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV52729808; called by muse, mutect2
- CXXC5 | c.648C>T p.I216= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56794058; called by muse, mutect2, varscan2
- DHX9 | c.2208G>A p.V736= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100841268, COSV62360073; called by muse, mutect2
- DLC1 | c.1272T>G p.S424= | Silent (SNP) | VAF 58/90 reads (64%) | catalogued as COSV52308596; called by muse, mutect2, varscan2
- DLG1 | c.2304G>A p.Q768= (on ENST00000419354 / NM_001290983.1; = p.Q790= on NM_004087.2) | Silent (SNP) | VAF 48/522 reads (9%) | catalogued as COSV58384375; called by muse, mutect2
- DNAJA2 | c.699C>T p.F233= | Silent (SNP) | VAF 58/273 reads (21%) | catalogued as COSV57694919, COSV57695366; called by muse, mutect2, varscan2
- DUSP15 | c.639G>A p.P213= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV54066508; called by muse, mutect2, varscan2
- EXO1 | c.1683T>C p.D561= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as rs754160967, COSV62217898; called by muse, mutect2, varscan2
- FAM131A | c.909A>G p.P303= (on ENST00000310585; = p.P334= on NM_144635.5) | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as COSV55601818; called by muse, mutect2
- FBN2 | c.4062G>C p.L1354= | Silent (SNP) | VAF 78/100 reads (78%) | catalogued as COSV52519263; called by muse, mutect2, varscan2
- FETUB | c.525T>C p.L175= | Silent (SNP) | VAF 33/449 reads (7%) | catalogued as rs757085308, COSV54006034; called by muse, mutect2
- FOXF2 | c.330C>T p.V110= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1027825657, COSV52526037; called by muse, mutect2, varscan2
- GARRE1 | c.2451C>A p.T817= | Silent (SNP) | VAF 69/202 reads (34%) | catalogued as COSV55100166; called by muse, mutect2, varscan2
- GPR149 | c.2031C>A p.P677= | Silent (SNP) | VAF 94/544 reads (17%) | catalogued as COSV67667388, COSV67667776; called by muse, mutect2, varscan2
- GPR183 | c.162C>T p.V54= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs1468630656, COSV63118507; called by muse, mutect2, varscan2
- HDAC7 | c.2061C>T p.I687= (on ENST00000427332; = p.I726= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as rs143801167; called by muse, mutect2, varscan2
- HSF4 | c.300G>A p.E100= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as COSV50457592; called by muse, mutect2, varscan2
- KCNG2 | c.888C>G p.L296= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV60268183; called by muse, mutect2, varscan2
- KCNK13 | c.744C>T p.N248= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs574638305, COSV56411938; called by muse, mutect2, varscan2
- LRRIQ1 | c.4452A>T p.S1484= | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as rs1565872215, COSV67832149; called by muse, mutect2, varscan2
- LRRIQ4 | c.369C>T p.L123= | Silent (SNP) | VAF 39/328 reads (12%) | catalogued as COSV61619391; called by muse, mutect2, varscan2
- MROH2B | c.81T>C p.I27= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV68185205; called by muse, mutect2, varscan2
- MUC4 | c.14838C>T p.N4946= (on ENST00000463781 / NM_018406.7; = p.N710= on NM_004532.6) | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as rs764418564, COSV57769735; called by muse, mutect2
- MUC5AC | c.13863A>G p.Q4621= | Silent (SNP) | VAF 58/176 reads (33%) | catalogued as COSV100611423; called by muse, mutect2, varscan2
- MYOCD | c.2658C>A p.P886= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV58505134; called by muse, mutect2, varscan2
- NECTIN2 | c.489G>A p.K163= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52977888; called by muse, mutect2, varscan2
- NEURL4 | c.264C>T p.T88= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV59759757; called by muse, mutect2, varscan2
- NXPE3 | c.1410C>G p.L470= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as COSV56290294; called by muse, mutect2
- OR13C4 | c.402C>T p.I134= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV52926909; called by muse, mutect2, varscan2
- OR6C1 | c.132C>A p.I44= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as COSV65573634, COSV65574530; called by muse, mutect2, varscan2
- PDE1C | c.2106C>T p.I702= | Silent (SNP) | VAF 52/478 reads (11%) | catalogued as rs761411793, COSV58509389; called by muse, varscan2
- PDZD2 | c.1641G>A p.L547= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV56860790, COSV56870855; called by muse, mutect2, varscan2
- PDZRN3 | c.2082C>T p.S694= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs1235293945, COSV55203186; called by muse, mutect2, varscan2
- PIWIL3 | c.1203G>C p.L401= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV59996102; called by muse, mutect2, varscan2
- PLEKHG4B | c.1503G>C p.L501= (on ENST00000283426; = p.L857= on NM_052909.5) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV52048848, COSV52052296; called by muse, mutect2, varscan2
- RXRA | c.321C>T p.I107= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV62684453; called by muse, mutect2, varscan2
- SCNN1D | c.1386C>G p.L462= (on ENST00000338555; = p.L626= on NM_001130413.4) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV57641940; called by muse, mutect2, varscan2
- SLC5A2 | c.105G>A p.L35= | Silent (SNP) | VAF 60/167 reads (36%) | catalogued as COSV57892262; called by muse, mutect2, varscan2
- TACR2 | c.597C>T p.L199= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100964811, COSV64822066; called by muse, mutect2
- TMEM94 | c.1098C>T p.L366= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1218654346, COSV58596600; called by muse, mutect2, varscan2
- TNS1 | c.1239C>A p.T413= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV50709879; called by muse, mutect2, varscan2
- TOX | c.1580G>A p.*527= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV63846941; called by muse, mutect2, varscan2
- TRHR | c.621T>A p.A207= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV61234627; called by muse, mutect2, varscan2
- TUBGCP2 | c.1173G>C p.L391= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV53305832, COSV99428221; called by muse, mutect2, varscan2
- UBXN11 | c.810C>G p.P270= (on ENST00000374221 / NM_183008.2; = p.P237= on NM_145345.2) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54625438; called by muse, mutect2, varscan2
- UROC1 | c.1257G>A p.E419= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1364211894, COSV52034301; called by muse, mutect2, varscan2
- UROC1 | c.1149G>C p.L383= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV52034331; called by muse, mutect2, varscan2
- WDR35 | c.2181C>T p.G727= (on ENST00000345530 / NM_001006657.2; = p.G716= on NM_020779.4) | Silent (SNP) | VAF 109/294 reads (37%) | catalogued as COSV55603728; called by muse, mutect2, varscan2
- ZDHHC14 | c.486G>T p.V162= | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as COSV58194638; called by muse, mutect2, varscan2
- ZNF208 | c.1818G>A p.E606= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV68107467; called by muse, mutect2, varscan2
- ZNRF3 | c.1470C>T p.L490= (on ENST00000544604 / NM_001206998.2; = p.L390= on NM_032173.3) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1371579139, COSV60431553, COSV60435083; called by muse, mutect2, varscan2
- ZSWIM5 | c.162C>A p.L54= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV62734765, COSV62736099; called by muse, mutect2, varscan2
- AFF3 | c.54-2618G>C | Intron (SNP) | VAF 50/202 reads (25%) | catalogued as COSV100418694, COSV57849000; called by muse, mutect2, varscan2
- CCNQP1 | n.198C>A | RNA (SNP) | VAF 78/209 reads (37%) | called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3943C>T | Intron (SNP) | VAF 31/105 reads (30%) | catalogued as COSV100504854; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6048904 G>C | 3'Flank (SNP) | VAF 14/64 reads (22%) | catalogued as COSV51533743; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22328G>A | Intron (SNP) | VAF 18/70 reads (26%) | catalogued as rs772031286, COSV67485240; called by muse, mutect2, varscan2
- KCNK7 | c.718+123G>A | Intron (SNP) | VAF 46/119 reads (39%) | catalogued as COSV100442151; called by muse, mutect2, varscan2
- MRPL33 | c.*3G>T | 3'UTR (SNP) | VAF 14/205 reads (7%) | catalogued as COSV99941395; called by muse, mutect2
- NRG1 | c.502+31102C>G | Intron (SNP) | VAF 32/95 reads (34%) | catalogued as COSV99828317; called by muse, mutect2, varscan2
- SNORD115-35 | n.14G>C | RNA (SNP) | VAF 11/351 reads (3%) | called by muse, mutect2
- SSPOP | n.976G>T | RNA (SNP) | VAF 17/150 reads (11%) | catalogued as COSV50487864; called by muse, mutect2
- TMEM132E | chr17:34579193 G>A | 5'Flank (SNP) | VAF 11/47 reads (23%) | catalogued as rs772164956; called by muse, mutect2, varscan2
- XIRP2 | c.*944G>A | 3'UTR (SNP) | VAF 30/85 reads (35%) | catalogued as rs749544496, COSV99742190; called by muse, mutect2, varscan2
